Somatic mutation profile of tumor specimen 0DKDDC from CCDI case PBBYCB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.0 years (5,830 days).
Specimen 0DKDDC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4fed166-51ec-477f-a9cd-61f279ac57d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKDC0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39c1f7b3-c27b-45df-b290-41bc1c7ce8c0

The open-access MAF lists 104 somatic variants for this specimen: 76 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 16, Intron 8, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 3, 5'UTR 2, 3'UTR 1, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 212/442 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 529/585 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTL7A | c.1035G>C p.K345N | Missense Mutation (SNP) | VAF 133/334 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV61777143; called by muse, mutect2, varscan2
- ADARB2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101187044; called by muse, mutect2, varscan2
- ATP9A | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 67/668 reads (10%) | catalogued as COSV58764480, COSV58764589; called by muse, mutect2, varscan2
- BANK1 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 181/534 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100536770; called by muse, mutect2, varscan2
- BCL9L | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 176/464 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1403588343; called by muse, mutect2, varscan2
- DNAH3 | c.8263G>A p.E2755K | Missense Mutation (SNP) | VAF 183/439 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759835468, COSV54509344; called by muse, mutect2, varscan2
- FAM47A | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as rs1312815547, COSV100650068; called by muse, mutect2, varscan2
- GALNT8 | c.1762-2A>G p.X588_splice | Splice Site (SNP) | VAF 26/133 reads (20%) | catalogued as rs746078045; called by muse, mutect2, varscan2
- HIP1 | c.1492A>G p.M498V | Missense Mutation (SNP) | VAF 27/813 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100416907; called by muse, mutect2
- HRNR | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 358/646 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as rs200265662; called by muse, mutect2
- IQSEC3 | c.1612C>T p.P538S (on ENST00000538872 / NM_001170738.2; = p.P235S on NM_015232.1) | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs782797045; called by muse, mutect2, varscan2
- LILRB2 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58749177; called by muse, mutect2, varscan2
- NFE2L1 | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1397563306; called by muse, mutect2
- POTEI | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.688); catalogued as rs765608903; called by mutect2, varscan2
- PREX2 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 25/676 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); catalogued as rs1291560005; called by muse, mutect2
- PTPRN | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 35/725 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0.068); catalogued as COSV55352835; called by muse, mutect2
- RB1CC1 | c.2034T>A p.D678E | Missense Mutation (SNP) | VAF 22/507 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV104377029; called by muse, mutect2
- SLC16A4 | c.1201A>G p.I401V | Missense Mutation (SNP) | VAF 66/672 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as rs897198910; called by muse, mutect2
- UBASH3A | c.1170G>C p.Q390H | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs1568926627; called by muse, mutect2, varscan2
- ZNF705G | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 25/625 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs754791974; called by muse, mutect2
- ABCB5 | c.920G>T p.W307L | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD36C | c.2548A>G p.R850G | Missense Mutation (SNP) | VAF 171/487 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- ARHGAP23 | c.3364T>A p.Y1122N | Missense Mutation (SNP) | VAF 36/745 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- ARPP21 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ATRX | c.4749_4752del p.K1583Nfs*22 | Frame Shift Del (DEL) | VAF 247/290 reads (85%) | called by mutect2, pindel, varscan2
- BBS12 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 24/620 reads (4%) | called by muse, mutect2
- CCDC157 | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 245/614 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CFAP20 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 44/744 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.199); called by muse, mutect2
- DECR1 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 296/670 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DEFB110 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 188/519 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DOCK4 | c.1358A>T p.E453V | Missense Mutation (SNP) | VAF 49/433 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- DOCK5 | c.3557T>C p.L1186P | Missense Mutation (SNP) | VAF 161/406 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EYS | c.5183del p.S1728Ifs*21 | Frame Shift Del (DEL) | VAF 214/563 reads (38%) | called by mutect2, pindel, varscan2
- FBN2 | c.3550G>A p.D1184N | Missense Mutation (SNP) | VAF 170/309 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCRL6 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FLG | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 20/664 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.26); called by muse, mutect2
- GPRIN2 | c.607del p.D203Tfs*36 | Frame Shift Del (DEL) | VAF 67/335 reads (20%) | called by mutect2, pindel, varscan2
- GRK3 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL27RA | c.1670A>G p.K557R | Missense Mutation (SNP) | VAF 125/619 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH4 | c.1423A>G p.T475A | Missense Mutation (SNP) | VAF 148/376 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KIRREL3 | c.1159T>A p.S387T | Missense Mutation (SNP) | VAF 283/875 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- KLF4 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 20/560 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- LRRK2 | c.871G>C p.V291L | Missense Mutation (SNP) | VAF 119/352 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- MRC1 | c.3419C>A p.A1140E | Missense Mutation (SNP) | VAF 26/652 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2
- MTUS1 | c.2450-1G>T p.X817_splice | Splice Site (SNP) | VAF 46/290 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.39532C>A p.L13178I | Missense Mutation (SNP) | VAF 110/422 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NPR1 | c.2003T>G p.V668G | Missense Mutation (SNP) | VAF 76/820 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR10A4 | c.643A>C p.I215L | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- OR4C12 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); called by muse, mutect2
- PCDH7 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- PDGFRA | c.691_696del p.I231_V232del | In Frame Del (DEL) | VAF 218/482 reads (45%) | called by pindel, varscan2
- PITPNM1 | c.2030C>G p.P677R | Missense Mutation (SNP) | VAF 43/824 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.031); called by muse, mutect2
- PPP1R42 | c.330A>C p.E110D | Missense Mutation (SNP) | VAF 25/438 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PSPC1 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 130/309 reads (42%) | called by muse, mutect2, varscan2
- RASEF | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 43/596 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGS22 | c.1879A>G p.I627V | Missense Mutation (SNP) | VAF 121/380 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- RIN3 | c.1559A>G p.H520R | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIN3 | c.2647T>G p.S883A | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- RWDD4 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 11/310 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2
- SEC22A | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 15/361 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- SEMA3A | c.1073A>G p.H358R | Missense Mutation (SNP) | VAF 23/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEPTIN12 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC7A4 | c.703T>C p.S235P | Missense Mutation (SNP) | VAF 20/633 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2
- SLITRK3 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPATA31A6 | c.1570T>C p.S524P | Missense Mutation (SNP) | VAF 132/161 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- TDRD9 | c.3282+1G>A p.X1094_splice | Splice Site (SNP) | VAF 16/360 reads (4%) | called by muse, mutect2
- TMEM52B | c.389C>T p.S130F (on ENST00000381923 / NM_001079815.1; = p.S110F on NM_153022.4) | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TTN | c.14879C>A p.P4960H (on ENST00000591111; = p.P4033H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/322 reads (10%) | PolyPhen probably damaging (0.964); called by muse, mutect2
- USH1C | c.1647-7C>A | Splice Region (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- USH2A | c.9097A>C p.S3033R | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- USP8 | c.1778T>G p.V593G | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- WNT3A | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 116/458 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- YEATS2 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 34/1012 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2
- ZFY | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 26/349 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.111); called by muse, mutect2
- AC008676.3 | c.45C>T p.I15= | Silent (SNP) | VAF 18/441 reads (4%) | called by muse, mutect2
- C1orf94 | c.1734A>G p.T578= (on ENST00000488417 / NM_001134734.2; = p.T388= on NM_032884.5) | Silent (SNP) | VAF 117/305 reads (38%) | called by muse, mutect2, varscan2
- CDH22 | c.2202G>A p.P734= | Silent (SNP) | VAF 90/234 reads (38%) | catalogued as rs1235953678; called by muse, mutect2, varscan2
- CPAMD8 | c.3759G>A p.S1253= (on ENST00000651564; = p.S1206= on NM_015692.5) | Silent (SNP) | VAF 80/324 reads (25%) | catalogued as rs779664080, COSV71596452, COSV71596636; called by muse, mutect2, varscan2
- GJA1 | c.567A>G p.R189= | Silent (SNP) | VAF 172/415 reads (41%) | called by muse, mutect2, varscan2
- JADE2 | c.87A>G p.R29= | Silent (SNP) | VAF 42/339 reads (12%) | catalogued as rs1170470458; called by muse, mutect2, varscan2
- MYBL1 | c.1230C>T p.N410= | Silent (SNP) | VAF 229/519 reads (44%) | catalogued as rs367803530, COSV72918880; called by muse, mutect2, varscan2
- NR5A2 | c.1014G>A p.K338= (on ENST00000367362 / NM_205860.3; = p.K292= on NM_003822.5) | Silent (SNP) | VAF 52/518 reads (10%) | called by muse, mutect2, varscan2
- OR8D2 | c.336C>A p.G112= | Silent (SNP) | VAF 40/402 reads (10%) | called by muse, mutect2
- PNISR | c.1350G>A p.R450= | Silent (SNP) | VAF 17/620 reads (3%) | called by muse, mutect2
- SLC27A1 | c.1461C>G p.A487= | Silent (SNP) | VAF 145/513 reads (28%) | called by muse, mutect2, varscan2
- SORCS2 | c.3168C>T p.G1056= | Silent (SNP) | VAF 133/324 reads (41%) | catalogued as rs199677935, COSV104411048; called by muse, mutect2, varscan2
- SPAG17 | c.5698C>T p.L1900= | Silent (SNP) | VAF 20/399 reads (5%) | called by muse, mutect2
- TMCO2 | c.69T>C p.N23= | Silent (SNP) | VAF 271/635 reads (43%) | called by muse, mutect2, varscan2
- TMEM132D | c.2529C>A p.G843= | Silent (SNP) | VAF 139/319 reads (44%) | called by mutect2, varscan2
- TRERF1 | c.1341C>T p.T447= | Silent (SNP) | VAF 97/260 reads (37%) | catalogued as COSV61676168; called by muse, mutect2, varscan2
- ADGRG7 | c.1110+55T>C | Intron (SNP) | VAF 40/52 reads (77%) | called by muse, mutect2, varscan2
- CCDC102A | c.1249-48C>A | Intron (SNP) | VAF 32/178 reads (18%) | called by muse, mutect2, varscan2
- DPH7 | c.776+33G>A | Intron (SNP) | VAF 29/196 reads (15%) | catalogued as rs781095270, COSV53023721; called by muse, mutect2, varscan2
- EME2 | c.-76A>T | 5'UTR (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- GPRC5C | c.-61C>A | 5'UTR (SNP) | VAF 24/59 reads (41%) | called by mutect2, varscan2
- MATK | c.583-64C>T | Intron (SNP) | VAF 19/63 reads (30%) | catalogued as rs760588198; called by muse, mutect2, varscan2
- MUC19 | n.6156G>T | RNA (SNP) | VAF 58/538 reads (11%) | called by mutect2, varscan2
- RMDN1 | c.730-64G>C | Intron (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2, varscan2
- SI | c.*95T>G | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- SYT7 | c.215+5237C>T | Intron (SNP) | VAF 138/327 reads (42%) | catalogued as rs969470690, COSV55655582; called by muse, mutect2, varscan2
- TSHZ2 | c.41-67907C>T | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- ZNF806 | n.295-2202C>T | Intron (SNP) | VAF 17/473 reads (4%) | called by muse, mutect2
